Somatic mutation profile of tumor specimen CDDP-ACR2-TTP1-A (aliquot CDDP-ACR2-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACR2, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79 years.
Specimen CDDP-ACR2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d00ef76-c346-4e52-927b-8a13b1ae580b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACR2-NB1-A (Blood Derived Normal), aliquot CDDP-ACR2-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7034ddd-4452-4f51-b98b-35ed8b11b9d3

The open-access MAF lists 199 somatic variants for this specimen: 130 protein-altering or splice-affecting, 42 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 42, Intron 16, Nonsense Mutation 9, 5'Flank 5, 5'UTR 3, Frame Shift Del 3, Splice Region 2, Splice Site 2, 3'UTR 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/660 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADGRL3 | c.1436C>T p.P479L (on ENST00000506720 / NM_001322402.2; = p.P411L on NM_015236.6) | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs369987771, COSV101547133; called by muse, mutect2, varscan2
- AGMO | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1369330744; called by muse, mutect2, varscan2
- ANK2 | c.7840G>C p.E2614Q | Missense Mutation (SNP) | VAF 62/661 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV52155032; called by muse, mutect2
- ANOS1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 42/596 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV52920672; called by muse, mutect2
- ANP32A | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 40/570 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1020600388; called by muse, mutect2
- ATL1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs972161717, COSV63296010; called by muse, mutect2, varscan2
- BCAR1 | c.2295C>G p.F765L | Missense Mutation (SNP) | VAF 70/463 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as COSV99365716; called by muse, mutect2, varscan2
- BTBD9 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs373397078, COSV104403735; called by muse, mutect2
- CC2D1B | c.2421T>A p.N807K | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs760652283; called by muse, mutect2, varscan2
- CMPK2 | c.158_175del p.G53_P58del | In Frame Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs1361573674; called by mutect2, varscan2
- CORIN | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV56691405; called by muse, mutect2, varscan2
- CREB3L2 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs1408025581; called by muse, mutect2
- CSMD1 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 30/546 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1563357110; called by muse, mutect2
- CSMD1 | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 31/554 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV101224098; called by muse, mutect2
- CSMD3 | c.9388G>A p.G3130S (on ENST00000297405 / NM_001363185.1; = p.G2961S on NM_052900.3) | Missense Mutation (SNP) | VAF 84/531 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs1428906513; called by muse, mutect2, varscan2
- CZIB | c.7-3C>T | Splice Region (SNP) | VAF 33/219 reads (15%) | catalogued as rs1437277945; called by muse, mutect2, varscan2
- DCAF12L1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1193953099; called by muse, mutect2
- DMD | c.6788G>A p.R2263H | Missense Mutation (SNP) | VAF 46/561 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.329); catalogued as rs780221745, COSV58891999; called by muse, mutect2
- DST | c.7352C>T p.S2451L | Missense Mutation (SNP) | VAF 56/597 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV55036252; called by muse, mutect2
- F8 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as CM062638; called by muse, mutect2
- FAM120C | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100070614; called by muse, mutect2, varscan2
- FBN2 | c.7530G>C p.E2510D | Missense Mutation (SNP) | VAF 42/597 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as COSV52491953, COSV52504235; called by muse, mutect2
- FCGBP | c.12224G>A p.R4075H | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.954); catalogued as rs777648366; called by muse, mutect2
- GRIK4 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1389864213; called by muse, mutect2, varscan2
- HNRNPR | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 38/318 reads (12%) | catalogued as COSV100164307, COSV100164684; called by muse, mutect2, varscan2
- ICAM5 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99320688; called by muse, mutect2, varscan2
- IFIT2 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as rs763699307, COSV51080124; called by muse, mutect2, varscan2
- IRX2 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 33/648 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs1245457090; called by muse, mutect2
- KCNJ2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 53/499 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs375330016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIG1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 169/613 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs776651223; called by muse, mutect2, varscan2
- LRRC45 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs376086300; called by muse, mutect2, varscan2
- MGA | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 76/251 reads (30%) | catalogued as COSV54954230; called by muse, mutect2, varscan2
- MYH2 | c.5497G>A p.E1833K | Missense Mutation (SNP) | VAF 76/544 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs193069934; called by muse, mutect2, varscan2
- NOSTRIN | c.1433G>C p.G478A (on ENST00000317647 / NM_001039724.4; = p.G400A on NM_052946.3) | Missense Mutation (SNP) | VAF 107/543 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58324395; called by muse, mutect2, varscan2
- OPN1SW | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 58/928 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99975426; called by muse, mutect2
- OR51M1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60785185; called by muse, mutect2, varscan2
- PLEKHG2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs750135156, COSV52679799; called by muse, mutect2
- PPP1R36 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs138901715; called by muse, mutect2, varscan2
- RELN | c.8336C>G p.S2779C | Missense Mutation (SNP) | VAF 52/834 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100632628; called by muse, mutect2
- RNF112 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1472516237; called by muse, mutect2, varscan2
- RNF115 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 62/596 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100991926; called by muse, mutect2, varscan2
- ROMO1 | c.128_129del p.L43Qfs*61 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as rs1355546897; called by pindel, varscan2
- SUN5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs929302638; called by muse, mutect2
- TEKT1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199498472, COSV58624074; called by muse, mutect2, varscan2
- TSPYL2 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 65/548 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs1556808386; called by muse, mutect2, varscan2
- TUBGCP3 | c.1468A>G p.I490V | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1485817539, COSV56188249; called by muse, mutect2
- ZBTB3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs1337774271; called by muse, mutect2, varscan2
- ZNF181 | c.1356G>C p.L452F | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV67627064; called by muse, mutect2, varscan2
- ZNF469 | c.11423G>C p.R3808T (on ENST00000437464; = p.R3836T on NM_001367624.2) | Missense Mutation (SNP) | VAF 120/632 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs1237385387; called by muse, mutect2, varscan2
- ABCB1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 78/542 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- AC005324.2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ANKLE1 | c.856G>A p.D286N (on ENST00000394458; = p.D232N on NM_152363.6) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- APCDD1L | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ASAP1 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 35/478 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); called by muse, mutect2
- BIRC5 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- BMP6 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 64/565 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC17 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2
- CDK19 | c.1031+1G>T p.X344_splice | Splice Site (SNP) | VAF 16/294 reads (5%) | called by muse, mutect2
- CDK5RAP2 | c.2471A>G p.E824G | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- CIT | c.4873C>T p.H1625Y | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- DIS3 | c.2825C>G p.S942* | Nonsense Mutation (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- DLG4 | c.2168G>C p.R723T (on ENST00000399506 / NM_001321075.3; = p.R766T on NM_001365.4) | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DOP1A | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, varscan2
- DYNLRB1 | c.3+3G>T | Splice Region (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2
- ELMO2 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EXPH5 | c.3503C>G p.S1168* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FOXD3 | c.624C>G p.N208K | Missense Mutation (SNP) | VAF 38/810 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- FSIP2 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- FUZ | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 87/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALM | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR152 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GPRC6A | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GRAMD1B | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- IGDCC3 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- INPP5B | c.791G>T p.G264V (on ENST00000373023; = p.G184V on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2
- ITGB1 | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 46/485 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- KCNB1 | c.1908G>T p.R636S | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF13A | c.2064G>C p.L688F | Missense Mutation (SNP) | VAF 48/550 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2
- LILRB3 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 106/787 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- LRFN4 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MAP4K1 | c.1307G>T p.S436I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ME1 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEIOC | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- MS4A13 | c.291G>C p.R97S | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MUC1 | c.3150T>G p.F1050L (on ENST00000611571 / NM_001371720.1; = p.F61L on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/458 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- NBPF11 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 21/878 reads (2%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2
- NCOA6 | c.1032G>A p.W344* | Nonsense Mutation (SNP) | VAF 28/360 reads (8%) | called by muse, mutect2
- NFS1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 50/607 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2
- OR51D1 | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- PCSK7 | c.2060A>T p.Y687F | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDCD11 | c.2592C>A p.F864L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- PPME1 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 45/594 reads (8%) | called by muse, mutect2
- PPP1R9A | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP2R5D | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- PTPN9 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 146/466 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRJ | c.3834G>T p.R1278S | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PTPRR | c.1555G>C p.V519L | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2
- RBM34 | c.850-1G>C p.X284_splice | Splice Site (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- RNF213 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 58/702 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2
- SBNO1 | c.2869C>G p.Q957E (on ENST00000420886; = p.Q956E on NM_018183.5) | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SCAF1 | c.3413G>C p.R1138T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.013); called by muse, varscan2
- SEC16A | c.3328C>T p.Q1110* | Nonsense Mutation (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- SIGIRR | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPART | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SPC25 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEG | c.9284C>T p.P3095L | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SPTBN1 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 30/631 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2
- SYT5 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TAF1 | c.1256C>G p.S419C (on ENST00000373790 / NM_138923.4; = p.S440C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TANC2 | c.5186_5187del p.C1729Sfs*17 | Frame Shift Del (DEL) | VAF 76/408 reads (19%) | called by mutect2, pindel, varscan2
- TCHP | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 33/554 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.751); called by muse, mutect2
- THG1L | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- TP53 | c.1045_1054del p.E349Mfs*18 | Frame Shift Del (DEL) | VAF 80/304 reads (26%) | called by mutect2, pindel, varscan2
- TRIM66 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 77/495 reads (16%) | called by muse, mutect2, varscan2
- TRMT12 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 35/408 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2
- TRMT9B | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, varscan2
- TUBB4B | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 34/1144 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2
- UBR3 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- UNC80 | c.3293C>A p.A1098E | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- USP28 | c.1454C>G p.S485C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- USP34 | c.3763C>G p.Q1255E | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.585); called by muse, mutect2
- UTP20 | c.6634G>A p.E2212K | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VEPH1 | c.808A>C p.N270H | Missense Mutation (SNP) | VAF 21/458 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2
- WASHC2C | c.3991T>A p.F1331I (on ENST00000336378; = p.F1310I on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- WASHC5 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF277 | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF479 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 32/490 reads (7%) | called by muse, mutect2
- ZNF480 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZNF628 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- APOE | c.510C>T p.A170= | Silent (SNP) | VAF 121/692 reads (17%) | catalogued as rs1235156724; called by muse, mutect2, varscan2
- ASXL1 | c.1383G>T p.L461= | Silent (SNP) | VAF 34/264 reads (13%) | catalogued as COSV100040435; called by muse, mutect2, varscan2
- B3GNT8 | c.669C>G p.L223= | Silent (SNP) | VAF 31/308 reads (10%) | catalogued as rs953447281, COSV54199269; called by muse, mutect2
- CACNA1F | c.999C>T p.T333= | Silent (SNP) | VAF 18/399 reads (5%) | catalogued as rs368889583, COSV100544688; called by muse, mutect2
- CAPN8 | c.1086C>T p.N362= | Silent (SNP) | VAF 65/416 reads (16%) | catalogued as rs751395423, COSV64817169; called by muse, mutect2, varscan2
- CBY2 | c.148C>T p.L50= | Silent (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.429C>T p.V143= | Silent (SNP) | VAF 49/471 reads (10%) | called by muse, mutect2, varscan2
- CLTC | c.3921G>A p.L1307= | Silent (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- CNTN3 | c.537G>A p.G179= | Silent (SNP) | VAF 78/718 reads (11%) | called by muse, mutect2, varscan2
- DGKB | c.430C>T p.L144= | Silent (SNP) | VAF 30/383 reads (8%) | called by muse, mutect2
- DNAJC1 | c.1455G>C p.L485= | Silent (SNP) | VAF 56/850 reads (7%) | catalogued as rs1246073449; called by muse, mutect2
- DYNLT3 | c.300C>T p.N100= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- FSCB | c.600A>G p.P200= | Silent (SNP) | VAF 71/337 reads (21%) | called by muse, mutect2, varscan2
- GGCX | c.487C>T p.L163= | Silent (SNP) | VAF 52/797 reads (7%) | called by muse, mutect2
- GPATCH8 | c.2239A>C p.R747= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1401035242; called by muse, mutect2, varscan2
- GPATCH8 | c.2238A>G p.R746= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs1395878556; called by muse, mutect2, varscan2
- GRIK3 | c.51C>T p.A17= | Silent (SNP) | VAF 48/484 reads (10%) | catalogued as rs1033577170; called by muse, mutect2, varscan2
- IFIT2 | c.360G>T p.V120= | Silent (SNP) | VAF 36/348 reads (10%) | catalogued as COSV51079115; called by muse, varscan2
- IL12RB2 | c.2028G>A p.K676= | Silent (SNP) | VAF 57/749 reads (8%) | catalogued as COSV52023977; called by muse, mutect2
- KDM3A | c.1147C>T p.L383= | Silent (SNP) | VAF 111/520 reads (21%) | catalogued as rs751690769; called by muse, mutect2, varscan2
- LRRC7 | c.246C>T p.F82= (on ENST00000651989 / NM_001370785.2; = p.F49= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 126/533 reads (24%) | catalogued as rs200701056, COSV50410646; called by muse, mutect2, varscan2
- MCTP1 | c.72C>G p.L24= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- MYH2 | c.2370G>A p.L790= | Silent (SNP) | VAF 101/652 reads (15%) | called by muse, mutect2, varscan2
- NEU4 | c.63C>A p.T21= (on ENST00000391969 / NM_001167602.3; = p.T33= on NM_080741.4) | Silent (SNP) | VAF 64/433 reads (15%) | called by muse, mutect2, varscan2
- PGPEP1 | c.555G>A p.L185= | Silent (SNP) | VAF 40/297 reads (13%) | catalogued as COSV53252122; called by muse, varscan2
- POLR3D | c.1011G>A p.V337= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as rs893133938; called by muse, mutect2
- POU2F2 | c.607C>T p.L203= (on ENST00000526816 / NM_001207025.3; = p.L187= on NM_002698.5) | Silent (SNP) | VAF 28/718 reads (4%) | catalogued as rs1164309137; called by muse, mutect2
- SARDH | c.1227C>T p.F409= | Silent (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- SEPHS1 | c.420G>A p.V140= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- SERPINE2 | c.210C>T p.D70= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as rs760828083, COSV51459312; called by muse, mutect2, varscan2
- SLC34A3 | c.1470C>T p.V490= | Silent (SNP) | VAF 35/293 reads (12%) | catalogued as rs754868140; called by muse, mutect2, varscan2
- SLC6A15 | c.810C>T p.I270= | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as rs971576157, COSV57022295; called by muse, mutect2, varscan2
- SMARCAL1 | c.1938C>G p.L646= | Silent (SNP) | VAF 49/452 reads (11%) | catalogued as rs1374217686; called by muse, mutect2, varscan2
- SNTA1 | c.1464C>T p.F488= | Silent (SNP) | VAF 68/672 reads (10%) | catalogued as COSV54128747, COSV54130201; called by muse, varscan2
- SYNM | c.432C>T p.L144= | Silent (SNP) | VAF 48/265 reads (18%) | called by muse, varscan2
- THEM6 | c.273G>A p.L91= | Silent (SNP) | VAF 23/293 reads (8%) | called by muse, mutect2
- TRIM66 | c.51C>G p.L17= | Silent (SNP) | VAF 38/206 reads (18%) | catalogued as rs773949396; called by muse, mutect2, varscan2
- UBN1 | c.1206G>A p.L402= | Silent (SNP) | VAF 36/339 reads (11%) | called by muse, mutect2, varscan2
- VWF | c.4803C>T p.P1601= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV54620708; called by muse, mutect2
- XXYLT1 | c.915C>G p.L305= | Silent (SNP) | VAF 14/410 reads (3%) | catalogued as rs1041052451; called by muse, mutect2
- ZNF2 | c.198G>A p.L66= | Silent (SNP) | VAF 37/397 reads (9%) | called by muse, mutect2, varscan2
- ZSCAN30 | c.1116C>T p.L372= | Silent (SNP) | VAF 39/358 reads (11%) | called by muse, mutect2, varscan2
- AGAP3 | c.1697-25G>A | Intron (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65502381 del TTTGTATTATC | 5'Flank (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- AP000769.3 | chr11:65502443 G>A | 5'Flank (SNP) | VAF 13/118 reads (11%) | called by muse, varscan2
- AP000769.3 | chr11:65502660 G>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- ASXL1 | c.980-22G>C | Intron (SNP) | VAF 49/614 reads (8%) | called by muse, mutect2
- BCL2L11 | c.394+4611G>A | Intron (SNP) | VAF 45/197 reads (23%) | catalogued as COSV100427326; called by muse, mutect2, varscan2
- C12orf50 | c.-96C>G | 5'UTR (SNP) | VAF 30/213 reads (14%) | called by muse, mutect2, varscan2
- CCBE1 | c.*15G>A | 3'UTR (SNP) | VAF 77/364 reads (21%) | catalogued as rs780416336; called by muse, mutect2, varscan2
- CD3E | c.352+47C>T | Intron (SNP) | VAF 121/523 reads (23%) | catalogued as rs199703386; called by muse, mutect2, varscan2
- GABPB1 | c.-1+304C>T | Intron (SNP) | VAF 28/144 reads (19%) | catalogued as rs901272790; called by muse, mutect2, varscan2
- IGSF21 | c.-38C>A | 5'UTR (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- KANSL3 | c.*2301G>C | 3'UTR (SNP) | VAF 49/320 reads (15%) | called by muse, varscan2
- LAG3 | c.1431+118G>A | Intron (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- LINC00917 | n.1332+12C>T | Intron (SNP) | VAF 36/260 reads (14%) | catalogued as rs1395172547; called by muse, mutect2, varscan2
- MAGEC3 | c.1728+11G>T | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53578176; called by mutect2, varscan2
- MRNIP | c.126+2072G>A | Intron (SNP) | VAF 68/508 reads (13%) | catalogued as rs1487615397; called by muse, mutect2, varscan2
- MTMR8 | c.-12G>A | 5'UTR (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- NCAM1 | c.1826-5566G>A | Intron (SNP) | VAF 105/560 reads (19%) | catalogued as rs201335423; called by muse, mutect2, varscan2
- NPAT | c.2786-28C>G | Intron (SNP) | VAF 36/309 reads (12%) | called by muse, mutect2, varscan2
- OR56B3P | n.417T>C | RNA (SNP) | VAF 40/361 reads (11%) | catalogued as rs749414427; called by muse, mutect2, varscan2
- PRR13 | c.19+15del | Intron (DEL) | VAF 26/286 reads (9%) | called by mutect2, pindel
- RBM3 | chrX:48574811 C>T | 5'Flank (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 26/469 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- RTBDN | c.462+330T>C | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as rs1426165164; called by muse, varscan2
- SPG7 | c.1429-701G>A | Intron (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- ZIC4 | c.688+1948C>A | Intron (SNP) | VAF 29/546 reads (5%) | called by muse, mutect2
- ZKSCAN8 | chr6:28136936 C>T | 5'Flank (SNP) | VAF 36/456 reads (8%) | catalogued as rs550689686; called by muse, mutect2
